Somatic mutation profile of tumor specimen C3N-01520-01 (aliquot CPT0076860009) from CPTAC case C3N-01520, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 69.9 years (25,521 days).
Specimen C3N-01520-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87e91838-743c-4efd-8005-b1bc9760a882.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01520-71 (Blood Derived Normal), aliquot CPT0076940002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b2198c9-eded-4c77-a3d8-0bd4d630eadd

The open-access MAF lists 4,841 somatic variants for this specimen: 3,063 protein-altering or splice-affecting, 1,151 silent, 627 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,574, Silent 1,151, Intron 315, Frame Shift Del 168, Nonsense Mutation 140, 3'UTR 95, RNA 79, Splice Site 78, 5'UTR 59, Splice Region 50, 5'Flank 48, Frame Shift Ins 39.

Variants (750 of 4,841; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD12 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 39/560 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1300228825; ClinVar: likely pathogenic; called by muse, mutect2
- ARID1A | c.6472C>T p.R2158* | Nonsense Mutation (SNP) | VAF 88/253 reads (35%) | hotspot (GDC flag); catalogued as COSV61370611, COSV61381711; called by muse, mutect2, varscan2
- BRCA2 | c.9097del p.T3033Lfs*29 | Frame Shift Del (DEL) | VAF 34/82 reads (41%) | catalogued as rs397507419; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- CARS1 | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as rs757978333; ClinVar: pathogenic; called by mutect2, varscan2
- COL4A5 | c.4614G>A p.W1538* | Nonsense Mutation (SNP) | VAF 59/374 reads (16%) | catalogued as rs104886294, CM960397, COSV60359865; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.8056T>C p.C2686R | Missense Mutation (SNP) | VAF 201/680 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1566889188, CM077257; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXG1 | c.460del p.E154Rfs*38 | Frame Shift Del (DEL) | VAF 16/144 reads (11%) | catalogued as rs398124204; ClinVar: pathogenic; called by mutect2, pindel
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.5521C>T p.Q1841* (on ENST00000358273 / NM_001042492.3; = p.Q1820* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 50/126 reads (40%) | catalogued as rs786203570, CD086559, CM990931, COSV62195584, COSV62202601; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NLRP7 | c.2471+1G>A p.X824_splice (on ENST00000340844 / NM_206828.3; = p.X796_splice on NM_139176.3) | Splice Site (SNP) | VAF 118/366 reads (32%) | catalogued as rs104895505, CS061310, COSV60178990; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1135_1137del p.K379del (on ENST00000521381 / NM_181523.3; = p.K109del on NM_181504.4) | In Frame Del (DEL) | VAF 14/23 reads (61%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PIK3R1 | c.1727_1729del p.T576del (on ENST00000521381 / NM_181523.3; = p.T306del on NM_181504.4) | In Frame Del (DEL) | VAF 14/65 reads (22%) | hotspot (GDC flag); catalogued as rs1057519842; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PMS2 | c.325del p.E109Kfs*3 | Frame Shift Del (DEL) | VAF 112/505 reads (22%) | catalogued as rs587781716, COSV56222390; ClinVar: pathogenic; called by pindel, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 27/68 reads (40%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SCNN1B | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs137852708, CM981791; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC1 | c.2692C>T p.Q898* | Nonsense Mutation (SNP) | VAF 66/194 reads (34%) | catalogued as rs118203728, CM981941; ClinVar: pathogenic / not provided; called by muse, varscan2
- A2M | c.2956G>A p.V986I | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.699); catalogued as rs754445861; called by muse, mutect2, varscan2
- ABCA1 | c.6532T>C p.Y2178H | Missense Mutation (SNP) | VAF 17/410 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as CM075933, COSV66069911; called by muse, mutect2
- ABCA2 | c.6364G>A p.A2122T (on ENST00000614293; = p.A2092T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/300 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99688411; called by muse, mutect2, varscan2
- ABCA2 | c.3563C>T p.A1188V (on ENST00000614293; = p.A1158V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 170/524 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778927183; called by muse, mutect2, varscan2
- ABCA3 | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 58/406 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.679); catalogued as rs1287712984, COSV100067985; called by muse, mutect2, varscan2
- ABCC3 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 116/385 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.116); catalogued as rs1292755800; called by muse, mutect2, varscan2
- ABCG1 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as rs758328427; called by muse, mutect2, varscan2
- ABHD14B | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 84/429 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as rs758354445; called by muse, mutect2, varscan2
- ABHD2 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 91/316 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766884528; called by muse, mutect2, varscan2
- ABLIM2 | c.469G>T p.G157C | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56400552, COSV99589634; called by muse, varscan2
- ACHE | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.065); catalogued as rs376949665; called by muse, mutect2, varscan2
- ACTN4 | c.306del p.K103Rfs*2 | Frame Shift Del (DEL) | VAF 80/243 reads (33%) | catalogued as rs1568719056; called by mutect2, pindel, varscan2
- ACTRT2 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs774253232; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS17 | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1006675474; called by muse, mutect2, varscan2
- ADAMTS9 | c.4235C>T p.S1412F | Missense Mutation (SNP) | VAF 82/253 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV55786238; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4123del p.Q1375Kfs*24 | Frame Shift Del (DEL) | VAF 58/178 reads (33%) | catalogued as COSV65879385; called by mutect2, varscan2
- ADAMTSL5 | c.140G>A p.C47Y | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953297719; called by muse, mutect2, varscan2
- ADCK2 | c.491G>A p.C164Y | Missense Mutation (SNP) | VAF 149/701 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1422620873; called by muse, mutect2, varscan2
- ADCY6 | c.2219C>T p.A740V | Missense Mutation (SNP) | VAF 86/303 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV57170542; called by muse, mutect2, varscan2
- ADD2 | c.485G>A p.S162N | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.06); catalogued as COSV104389224; called by muse, mutect2, varscan2
- ADGB | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV58855321; called by muse, mutect2
- ADGRA2 | c.3257del p.P1086Lfs*217 | Frame Shift Del (DEL) | VAF 55/152 reads (36%) | catalogued as rs1189742043; called by mutect2, pindel, varscan2
- ADNP2 | c.971del p.P324Lfs*8 | Frame Shift Del (DEL) | VAF 20/231 reads (9%) | catalogued as rs772825390; called by mutect2, pindel
- ADRA1D | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as rs1439012272; called by muse, mutect2, varscan2
- ADRB3 | c.956del p.G319Afs*4 | Frame Shift Del (DEL) | VAF 229/795 reads (29%) | catalogued as rs1563397465; called by mutect2, pindel, varscan2
- AGO2 | c.1891G>A p.V631M | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs1035096734; called by muse, mutect2, varscan2
- AGO2 | c.1358T>C p.I453T | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1323817642; called by muse, mutect2, varscan2
- AGRN | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 92/303 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65072353; called by muse, mutect2, varscan2
- AGXT | c.1019T>C p.I340T | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs749568989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHNAK | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 103/226 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.116); catalogued as rs777135489; called by muse, mutect2, varscan2
- AHNAK2 | c.9198G>A p.M3066I | Missense Mutation (SNP) | VAF 119/345 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.316); catalogued as rs377123111; called by muse, mutect2, varscan2
- AJM1 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1317335613, COSV56032723; called by muse, mutect2, varscan2
- AK7 | c.1673G>T p.S558I | Missense Mutation (SNP) | VAF 148/449 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs1393526425; called by muse, mutect2, varscan2
- AKIRIN1 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV100881972; called by muse, mutect2, varscan2
- AL136295.3 | c.523del p.G175Afs*15 | Frame Shift Del (DEL) | VAF 54/162 reads (33%) | catalogued as rs760463204; called by mutect2, varscan2
- ALG10B | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100440027; called by muse, mutect2, varscan2
- ALOXE3 | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs1381168698; called by muse, mutect2, varscan2
- ALPK1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs763029486; called by muse, mutect2, varscan2
- AMFR | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769305833; called by muse, varscan2
- ANK1 | c.4472G>A p.R1491H | Missense Mutation (SNP) | VAF 101/620 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.503); catalogued as rs372878614; called by muse, mutect2, varscan2
- ANK3 | c.10883G>T p.R3628M | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV99782541; called by muse, mutect2, varscan2
- ANKH | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 40/724 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as rs892060321; called by muse, mutect2
- ANKRD30A | c.1252G>A p.A418T (on ENST00000611781; = p.A362T on NM_052997.2) | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs372362957; called by muse, mutect2, varscan2
- ANKRD31 | c.1533del p.G512Vfs*20 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | catalogued as rs1279723268; called by mutect2, pindel, varscan2
- ANKRD52 | c.1913C>T p.T638I | Missense Mutation (SNP) | VAF 166/603 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs747561006; called by muse, mutect2, varscan2
- ANKRD52 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 190/550 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.163); catalogued as rs770238856; called by muse, mutect2, varscan2
- ANKS1A | c.2231G>A p.S744N | Missense Mutation (SNP) | VAF 98/306 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.111); catalogued as rs1343627127; called by muse, mutect2, varscan2
- ANO3 | c.2552C>T p.A851V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV56788995; called by muse, mutect2, varscan2
- ANPEP | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 102/293 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as rs201493541; called by muse, mutect2, varscan2
- AP1B1 | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 100/314 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs546260476; called by muse, mutect2
- AP3M1 | c.474dup p.T159Hfs*20 | Frame Shift Ins (INS) | VAF 62/235 reads (26%) | catalogued as rs34222970; called by pindel, varscan2
- APAF1 | c.3416G>C p.S1139T (on ENST00000551964 / NM_181861.2; = p.S1085T on NM_001160.3) | Missense Mutation (SNP) | VAF 181/591 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as COSV100244492; called by muse, mutect2, varscan2
- APBA2 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 151/495 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs748959948; called by muse, mutect2, varscan2
- APC | c.3295G>A p.V1099I | Missense Mutation (SNP) | VAF 94/326 reads (29%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.108); catalogued as rs730881245, CD930895, COSV57381507, COSV57384626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.4390G>A p.E1464K | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as CM1110505, COSV57338936, COSV57352863; called by muse, mutect2, varscan2
- APLP1 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 84/304 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs768272777, COSV55707182; called by muse, mutect2, varscan2
- APOB | c.9149C>T p.T3050I | Missense Mutation (SNP) | VAF 67/224 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs766404863; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP7 | c.496A>G p.M166V | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs774369511; called by muse, mutect2, varscan2
- ARAP3 | c.2816G>A p.G939D | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs746607535; called by muse, varscan2
- ARFGEF1 | c.3473C>T p.T1158M | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as rs1288100333; called by muse, mutect2, varscan2
- ARFIP2 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 89/281 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772069696; called by muse, mutect2, varscan2
- ARHGAP24 | c.1447C>T p.R483C (on ENST00000395184 / NM_001025616.3; = p.R390C on NM_031305.3) | Missense Mutation (SNP) | VAF 135/400 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs777874622, COSV51991517; called by muse, mutect2, varscan2
- ARHGAP31 | c.675G>T p.E225D | Missense Mutation (SNP) | VAF 128/438 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV51801105; called by muse, mutect2, varscan2
- ARHGAP33 | c.2600C>A p.P867H | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV99139448; called by muse, mutect2, varscan2
- ARHGAP44 | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1427558525; called by muse, mutect2, varscan2
- ARHGAP5 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV61535308; called by muse, mutect2, varscan2
- ARHGEF17 | c.5855C>T p.T1952I | Missense Mutation (SNP) | VAF 187/501 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV55231528; called by muse, mutect2, varscan2
- ARSJ | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104408954; called by muse, mutect2, varscan2
- ASAH1 | c.862A>G p.K288E | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as rs1380347230; called by muse, mutect2, varscan2
- ASB10 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs151344615; called by muse, mutect2, varscan2
- ASGR2 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs905736646; called by muse, mutect2, varscan2
- ASXL2 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 44/166 reads (27%) | catalogued as COSV55453315, COSV55459595; called by muse, mutect2, varscan2
- ATF7IP | c.3589C>A p.H1197N | Missense Mutation (SNP) | VAF 83/379 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99661980; called by muse, mutect2, varscan2
- ATIC | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 118/373 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs150438200; called by muse, mutect2, varscan2
- ATM | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs864622650, COSV53787787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B3 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs924902616, COSV54842708; called by muse, mutect2, varscan2
- ATP4B | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs764891890; called by muse, mutect2
- ATP5PB | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV63853786; called by muse, mutect2, varscan2
- ATP6V0A4 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 156/774 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.397); catalogued as rs1277901726; called by muse, mutect2, varscan2
- ATP6V1C1 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1317485078, COSV101215160; called by muse, mutect2, varscan2
- ATP9A | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 27/140 reads (19%) | catalogued as rs937920116; called by muse, mutect2, varscan2
- ATXN7L1 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as rs757853084, COSV66300207; called by muse, mutect2, varscan2
- AXL | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); catalogued as rs148886744; called by muse, mutect2, varscan2
- BACH1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs553355487, COSV54520919; called by muse, mutect2, varscan2
- BAZ1A | c.3040C>T p.R1014W | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs151068420; called by muse, mutect2, varscan2
- BAZ2A | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 133/441 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs941291424; called by muse, mutect2, varscan2
- BCCIP | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.617); catalogued as rs886792383; called by muse, mutect2, varscan2
- BCL6 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 157/495 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as rs752135848; called by muse, mutect2, varscan2
- BCL9L | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs779113412; called by muse, mutect2, varscan2
- BCR | c.1396C>A p.L466I | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100006366; called by muse, mutect2, varscan2
- BEST4 | c.1312del p.R438Afs*82 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | catalogued as rs755252994; called by mutect2, pindel, varscan2
- BIN2 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 54/203 reads (27%) | catalogued as rs748291125; called by muse, mutect2, varscan2
- BIRC7 | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 76/218 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV53903348; called by muse, mutect2, varscan2
- BOD1L1 | c.4361C>T p.T1454I | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs186263512; called by muse, mutect2, varscan2
- BRAT1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs112960104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD1 | c.2894C>T p.P965L (on ENST00000216267 / NM_001349940.1; = p.P1096L on NM_001304808.3) | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773696652; called by muse, varscan2
- BRINP2 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1419220723, COSV64175373; called by muse, mutect2, varscan2
- BRINP3 | c.2075C>G p.T692S | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as COSV66522803; called by muse, mutect2, varscan2
- BTN2A2 | c.1156G>A p.V386M | Missense Mutation (SNP) | VAF 44/396 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1265579092; called by muse, mutect2, varscan2
- BTNL8 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs750107545; called by muse, mutect2, varscan2
- BUB1 | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1414411465; called by muse, mutect2
- C10orf71 | c.1405C>A p.P469T | Missense Mutation (SNP) | VAF 146/450 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.415); catalogued as COSV100110093; called by muse, mutect2, varscan2
- C11orf45 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV57971036; called by muse, varscan2
- C1GALT1C1L | c.845del p.K282Rfs*4 | Frame Shift Del (DEL) | VAF 12/136 reads (9%) | catalogued as rs748029349; called by mutect2, pindel
- C1orf94 | c.1583C>A p.P528H (on ENST00000488417 / NM_001134734.2; = p.P338H on NM_032884.5) | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100975174; called by muse, mutect2, varscan2
- C2orf73 | c.309del p.F103Lfs*17 | Frame Shift Del (DEL) | VAF 19/141 reads (13%) | catalogued as rs747496393; called by mutect2, pindel, varscan2
- C3orf62 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 98/329 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV55540634; called by muse, mutect2, varscan2
- C4A | c.2677T>A p.S893T | Missense Mutation (SNP) | VAF 277/1664 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV71177559; called by muse, mutect2, varscan2
- C4orf3 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs938411346; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 99/331 reads (30%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- CABP4 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 203/612 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1031406409, COSV56887942; called by muse, mutect2, varscan2
- CACNA1A | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as COSV64204342; called by muse, mutect2, varscan2
- CACNA1C | c.5052G>T p.K1684N | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV59707045; called by muse, mutect2, varscan2
- CACNA1E | c.6611A>G p.N2204S (on ENST00000367573 / NM_001205293.3; = p.N2161S on NM_000721.4) | Missense Mutation (SNP) | VAF 93/286 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs923912118; called by muse, mutect2, varscan2
- CACNA1G | c.3932C>G p.T1311S | Missense Mutation (SNP) | VAF 84/258 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.023); catalogued as rs773421114; called by muse, mutect2, varscan2
- CACNA1S | c.1730G>A p.G577D | Missense Mutation (SNP) | VAF 202/645 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62935588; called by muse, mutect2, varscan2
- CACNA2D2 | c.993G>A p.S331= | Splice Region (SNP) | VAF 78/226 reads (35%) | catalogued as rs780661542, COSV56568964; called by muse, mutect2, varscan2
- CALCRL | c.48del p.F16Lfs*2 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as rs1486659949; called by mutect2, varscan2
- CALN1 | c.262G>A p.G88R (on ENST00000329008 / NM_001017440.3; = p.G130R on NM_031468.4) | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs756722744; called by muse, mutect2, varscan2
- CAND1 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as rs758425607; called by muse, mutect2, varscan2
- CASKIN1 | c.1850C>A p.P617H | Missense Mutation (SNP) | VAF 135/397 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as rs776859432; called by muse, mutect2, varscan2
- CATSPER4 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 72/635 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.147); catalogued as rs371089081; called by muse, mutect2, varscan2
- CBX4 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs201691344; called by muse, mutect2, varscan2
- CC2D2A | c.200A>T p.E67V (on ENST00000424120 / NM_001378615.1; = p.G102= on NM_020785.2) | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV67505983; called by muse, mutect2
- CCDC114 | c.1436G>A p.S479N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs758487756; called by muse, mutect2, varscan2
- CCDC120 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs782022133; called by muse, mutect2
- CCDC141 | c.4159G>A p.V1387I | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.059); catalogued as rs759550127, COSV55377605, COSV55380753; called by muse, mutect2, varscan2
- CCDC17 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1557680538; called by muse, mutect2, varscan2
- CCDC73 | c.2014del p.S672Vfs*22 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as rs747131147; called by mutect2, pindel, varscan2
- CCNB3 | c.2743G>A p.A915T | Missense Mutation (SNP) | VAF 97/327 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.108); catalogued as rs1557214753; called by muse, mutect2, varscan2
- CD2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 140/423 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101040226; called by muse, mutect2, varscan2
- CD22 | c.1997G>A p.G666D | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286507402; called by muse, mutect2, varscan2
- CD300A | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 89/293 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as rs199846807; called by muse, mutect2, varscan2
- CD3E | c.242A>G p.H81R | Missense Mutation (SNP) | VAF 136/332 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV62346767; called by muse, mutect2, varscan2
- CDH23 | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 37/603 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54934267; called by muse, mutect2
- CDH4 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 74/237 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs149315148; called by muse, mutect2, varscan2
- CDH9 | c.1957C>T p.R653W | Missense Mutation (SNP) | VAF 73/287 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50320975, COSV99142080; called by muse, mutect2, varscan2
- CDHR2 | c.2363del p.G788Vfs*4 | Frame Shift Del (DEL) | VAF 21/97 reads (22%) | catalogued as rs868286996; called by mutect2, pindel, varscan2
- CDHR5 | c.2378C>T p.T793M (on ENST00000358353 / NM_001171968.2; = p.T799M on NM_021924.5) | Missense Mutation (SNP) | VAF 48/554 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs149934780; called by muse, mutect2
- CDK16 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1174157801; called by muse, mutect2, varscan2
- CDKN2B | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 283/823 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.569); catalogued as rs765231771; called by muse, mutect2, varscan2
- CELF4 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1340223204, COSV100611728; called by muse, mutect2
- CELSR1 | c.5544del p.T1849Rfs*8 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | catalogued as rs776824429; called by mutect2, pindel
- CELSR1 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs1181313170; called by muse, mutect2, varscan2
- CELSR3 | c.8297C>T p.A2766V | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs755164071; called by muse, mutect2, varscan2
- CEMIP2 | c.2282A>G p.Q761R | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs1432898282; called by muse, mutect2
- CEND1 | c.298G>T p.G100W | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV57192414; called by muse, varscan2
- CENPE | c.964-5del | Splice Region (DEL) | VAF 12/36 reads (33%) | catalogued as rs747346342; called by mutect2, varscan2
- CEP104 | c.2476A>G p.R826G | Missense Mutation (SNP) | VAF 117/339 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1377860779; called by muse, mutect2, varscan2
- CEP128 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as rs774385928; called by muse, mutect2, varscan2
- CEP170B | c.3187G>A p.A1063T (on ENST00000453495; = p.A992T on NM_015005.3) | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV69026767; called by muse, mutect2, varscan2
- CEP72 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370257753; called by muse, mutect2, varscan2
- CFAP57 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 95/277 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs1472128541, COSV65263456; called by muse, mutect2, varscan2
- CFAP57 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 153/552 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as rs1331230385, COSV65265421; called by muse, mutect2, varscan2
- CFAP58 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as rs1466599068; called by muse, mutect2, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 94/278 reads (34%) | catalogued as rs778664468; called by mutect2, varscan2
- CHCHD3 | c.661-1G>A p.X221_splice | Splice Site (SNP) | VAF 19/99 reads (19%) | catalogued as COSV99067779; called by muse, mutect2, varscan2
- CHID1 | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs147404587; called by muse, mutect2, varscan2
- CHPF | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370676153; called by muse, mutect2, varscan2
- CHRM3 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as rs145759529; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 70/251 reads (28%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRM4 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 77/242 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.42); catalogued as rs376964131; called by muse, mutect2, varscan2
- CHST2 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1309715355, COSV58887080; called by muse, mutect2, varscan2
- CHST6 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 173/483 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377706989, CM032875, CM034089, CX033312, COSV60000058; called by muse, mutect2, varscan2
- CHTF18 | c.2477G>A p.R826H | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs759199021; called by muse, mutect2, varscan2
- CIAO3 | c.1384T>A p.Y462N | Missense Mutation (SNP) | VAF 161/441 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52403510; called by muse, mutect2, varscan2
- CITED2 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.188); catalogued as rs763869620; called by muse, mutect2, varscan2
- CKAP4 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs749256244, COSV100952516; called by muse, mutect2, varscan2
- CLIP2 | c.2480-4C>A | Splice Region (SNP) | VAF 104/455 reads (23%) | catalogued as COSV56280337; called by muse, mutect2, varscan2
- CLTCL1 | c.2893C>T p.P965S | Missense Mutation (SNP) | VAF 87/253 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.042); catalogued as COSV54233863, COSV54240478; called by muse, mutect2, varscan2
- CLTCL1 | c.2623A>G p.T875A | Missense Mutation (SNP) | VAF 73/248 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs188522385; called by muse, mutect2, varscan2
- CNGA3 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 36/460 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV55622012; called by muse, mutect2
- CNGB1 | c.2370-1G>T p.X790_splice | Splice Site (SNP) | VAF 144/401 reads (36%) | catalogued as COSV99201758; called by muse, mutect2, varscan2
- CNMD | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV65033760; called by muse, mutect2, varscan2
- CNTNAP2 | c.1997G>A p.S666N | Missense Mutation (SNP) | VAF 213/971 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs200098672; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.3412C>G p.L1138V | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs751591690, COSV101443090; called by muse, mutect2, varscan2
- COL18A1 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 169/497 reads (34%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs1216249534; called by muse, mutect2, varscan2
- COL19A1 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 75/231 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs201036860, COSV59569463; called by muse, mutect2, varscan2
- COL5A1 | c.5294G>A p.R1765H | Missense Mutation (SNP) | VAF 148/483 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs150608071; called by muse, mutect2, varscan2
- COL6A2 | c.2780C>T p.A927V | Missense Mutation (SNP) | VAF 261/682 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as rs11554668; called by muse, mutect2, varscan2
- COL6A6 | c.4815G>T p.Q1605H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1438556349; called by muse, mutect2, varscan2
- COL6A6 | c.5626G>A p.A1876T | Missense Mutation (SNP) | VAF 27/366 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1284687222, COSV100650756; called by muse, mutect2
- COL9A1 | c.1820G>A p.G607D | Missense Mutation (SNP) | VAF 163/696 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100295965; called by muse, mutect2, varscan2
- COPB1 | c.1924A>G p.M642V | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); catalogued as rs1321494135; called by muse, mutect2, varscan2
- COPG1 | c.2528G>T p.R843L | Missense Mutation (SNP) | VAF 109/345 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV59114618; called by muse, mutect2, varscan2
- COQ8A | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 139/434 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV64659006; called by muse, mutect2, varscan2
- CORO2A | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as COSV59663365; called by muse, mutect2, varscan2
- COX6A2 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs978580253, COSV54931945; called by muse, mutect2, varscan2
- COX6B1 | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs377025450; called by muse, mutect2, varscan2
- CPA2 | c.959G>A p.C320Y | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs769146869; called by muse, mutect2, varscan2
- CPXM2 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 133/364 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.437); catalogued as rs940829569; called by muse, mutect2, varscan2
- CPZ | c.709+1G>A p.X237_splice (on ENST00000360986 / NM_001014447.3; = p.X226_splice on NM_003652.3) | Splice Site (SNP) | VAF 34/98 reads (35%) | catalogued as rs1359342515; called by muse, mutect2, varscan2
- CR1 | c.4401G>T p.M1467I | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.228); catalogued as rs751449981; called by muse, mutect2, varscan2
- CRISPLD1 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as rs1399611349; called by muse, mutect2, varscan2
- CRMP1 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 121/326 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100271910; called by muse, mutect2, varscan2
- CROT | c.725G>A p.S242N | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs1375565494; called by muse, mutect2, varscan2
- CSF1 | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as rs1405845260; called by muse, mutect2, varscan2
- CSMD2 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 114/305 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745859854, COSV53932345; called by muse, mutect2, varscan2
- CSPG4 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 36/333 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs376418566; called by muse, mutect2, varscan2
- CSPG5 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.087); catalogued as COSV99273679; called by muse, mutect2, varscan2
- CTAGE6 | c.1412C>G p.T471S | Missense Mutation (SNP) | VAF 56/582 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.46); catalogued as rs766712744, COSV69917108; called by muse, mutect2, varscan2
- CTBS | c.1073G>A p.C358Y | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.079); catalogued as rs1304958373; called by muse, mutect2
- CTCF | c.1546A>G p.T516A | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.51); catalogued as COSV50463289; called by muse, mutect2
- CTDP1 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 52/619 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs953525649; called by muse, mutect2
- CTDSP2 | c.623G>T p.R208M | Missense Mutation (SNP) | VAF 134/342 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66080162; called by muse, mutect2, varscan2
- CTNNA2 | c.1333del p.V445* | Frame Shift Del (DEL) | VAF 69/198 reads (35%) | catalogued as COSV58171855; called by mutect2, pindel, varscan2
- CUL2 | c.1190A>G p.N397S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs201586230; called by muse, mutect2, varscan2
- CWH43 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99892742; called by muse, mutect2, varscan2
- CYBB | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 37/142 reads (26%) | catalogued as CM158094; called by muse, mutect2, varscan2
- CYHR1 | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV101446332; called by muse, mutect2, varscan2
- CYP2A7 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV52504315; called by muse, mutect2, varscan2
- CYP2C9 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 257/831 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs200183364, CM087577; called by muse, mutect2, varscan2
- CYP2F1 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100462539; called by muse, mutect2, varscan2
- CYP2F1 | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs772809858; called by muse, mutect2, varscan2
- CYP4B1 | c.806A>G p.Q269R | Missense Mutation (SNP) | VAF 65/255 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV54726150; called by muse, mutect2, varscan2
- CYP4F2 | c.1244C>A p.P415H | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777110454; called by muse, mutect2, varscan2
- CYP4F22 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs1256722526; called by muse, mutect2
- DAB2IP | c.2864C>T p.S955L (on ENST00000408936; = p.S927L on NM_032552.3) | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs1186415489; called by muse, mutect2, varscan2
- DAG1 | c.2234G>A p.S745N | Missense Mutation (SNP) | VAF 288/862 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV100445031; called by muse, mutect2, varscan2
- DAGLA | c.2183A>G p.Q728R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV57194216; called by muse, varscan2
- DAPK2 | c.707T>C p.L236P | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56045059; called by muse, mutect2, varscan2
- DCAF8L1 | c.1364G>A p.S455N | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV71595132; called by muse, mutect2, varscan2
- DCLRE1C | c.1310G>A p.R437K (on ENST00000378278 / NM_001350965.2; = p.R322K on NM_022487.4) | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1238627850, COSV57955940; called by muse, mutect2, varscan2
- DDAH2 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 17/270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375404521; called by muse, mutect2
- DEF8 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 76/257 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1385331398; called by muse, mutect2, varscan2
- DENND1C | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 80/320 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.18); catalogued as rs749073599; called by muse, mutect2, varscan2
- DENND5A | c.3638G>A p.G1213D | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60232818, COSV60234314; called by muse, mutect2, varscan2
- DEPTOR | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 99/285 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs201515307, COSV53818010; called by muse, mutect2, varscan2
- DES | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 22/443 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.919); catalogued as rs1163703259; called by muse, mutect2
- DGKG | c.1711G>T p.G571W | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53963889; called by muse, mutect2, varscan2
- DHRS2 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.248); catalogued as COSV51631258; called by muse, mutect2, varscan2
- DHX16 | c.524T>C p.L175P | Missense Mutation (SNP) | VAF 117/353 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.69); catalogued as COSV64580340; called by muse, mutect2, varscan2
- DIDO1 | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 168/538 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs759817028, COSV56633888; called by muse, mutect2, varscan2
- DIP2B | c.4101G>T p.K1367N | Missense Mutation (SNP) | VAF 29/367 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV99998369; called by muse, mutect2
- DISP2 | c.3143G>A p.R1048H | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1188349236; called by muse, mutect2, varscan2
- DMAC2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); catalogued as rs782665880; called by muse, mutect2, varscan2
- DMXL2 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.677); catalogued as rs754547956; called by muse, mutect2
- DNAH10 | c.2812C>A p.L938M (on ENST00000409039; = p.L877M on NM_207437.3) | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV101292102; called by muse, mutect2, varscan2
- DNAH11 | c.8285G>A p.R2762K | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758580853; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH14 | c.4991G>A p.C1664Y (on ENST00000445597; = p.C2069Y on NM_001367479.1) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as rs769365974; called by muse, mutect2, varscan2
- DNAH17 | c.10316C>T p.P3439L | Missense Mutation (SNP) | VAF 146/440 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752234872, COSV67749542; called by muse, mutect2, varscan2
- DNAH8 | c.5605G>A p.V1869M | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs748005521, COSV59478807; called by muse, mutect2, varscan2
- DNAJA3 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as rs764969884; called by muse, mutect2, varscan2
- DNAJA3 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 72/247 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1259962225, COSV99276678; called by muse, varscan2
- DNAJB8 | c.433A>G p.M145V | Missense Mutation (SNP) | VAF 100/260 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs748041270, COSV59879714; called by muse, mutect2, varscan2
- DNAJC14 | c.1737G>A p.M579I | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs1047421032; called by muse, mutect2
- DPP6 | c.2564C>T p.T855I (on ENST00000377770 / NM_001364500.2; = p.T793I on NM_001936.5) | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100124930; called by muse, mutect2
- DPY19L2 | c.1359C>T p.H453= | Splice Region (SNP) | VAF 6/40 reads (15%) | catalogued as rs1419970070; called by muse, mutect2, varscan2
- DPYSL5 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 94/236 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs1444282863, COSV56515347; called by muse, varscan2
- DRD2 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 100/385 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199961459; called by muse, mutect2, varscan2
- DSTYK | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 73/330 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs535442055; called by muse, mutect2, varscan2
- DSTYK | c.1277C>T p.T426I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs143291000; called by muse, mutect2, varscan2
- DTX2 | c.1292G>A p.S431N | Missense Mutation (SNP) | VAF 60/336 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as rs779910965; called by muse, mutect2
- DYNC1I1 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100267572; called by muse, mutect2, varscan2
- E2F1 | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as rs151195835; called by muse, mutect2, varscan2
- EBF1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768501688, COSV58175661; called by muse, mutect2, varscan2
- EFCAB6 | c.4321C>T p.R1441C | Missense Mutation (SNP) | VAF 126/455 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372168931, COSV53061785, COSV53066189; called by muse, mutect2, varscan2
- EHBP1L1 | c.3022G>A p.A1008T | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as rs888015254; called by muse, mutect2, varscan2
- EHBP1L1 | c.4232T>C p.L1411P | Missense Mutation (SNP) | VAF 130/391 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100442093; called by muse, mutect2, varscan2
- EHMT2 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.739); catalogued as COSV64994225; called by muse, mutect2, varscan2
- EIF3B | c.2142G>T p.Q714H | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.332); catalogued as COSV100703749; called by muse, mutect2, varscan2
- EIF3F | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.158); catalogued as rs771243784; called by muse, mutect2
- EIF4A2 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs11538614; called by muse, mutect2, varscan2
- ELP1 | c.626_627del p.V209Efs*26 | Frame Shift Del (DEL) | VAF 104/417 reads (25%) | catalogued as rs765038815; called by pindel, varscan2
- ENTHD1 | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV57319067; called by muse, mutect2, varscan2
- EP300 | c.377T>C p.M126T | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.684); catalogued as rs746019881; called by muse, mutect2, varscan2
- EPAS1 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 160/492 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs749317556, COSV55389104; called by muse, mutect2, varscan2
- EPHA4 | c.2599G>A p.D867N | Missense Mutation (SNP) | VAF 129/371 reads (35%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.745); catalogued as rs745528063; called by muse, mutect2, varscan2
- EPHA6 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1284951409; called by muse, mutect2, varscan2
- EPOR | c.1082G>A p.S361N | Missense Mutation (SNP) | VAF 49/496 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as rs569851700; called by muse, mutect2, varscan2
- EPPK1 | c.5724G>T p.R1908S | Missense Mutation (SNP) | VAF 91/266 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV73260884; called by muse, mutect2, varscan2
- EPS8L3 | c.932C>A p.P311H | Missense Mutation (SNP) | VAF 62/239 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV104422866; called by muse, mutect2, varscan2
- ERAP1 | c.38T>C p.M13T | Missense Mutation (SNP) | VAF 91/347 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1444094861; called by muse, mutect2, varscan2
- ERBB2 | c.643+1G>A p.X215_splice | Splice Site (SNP) | VAF 76/295 reads (26%) | catalogued as rs113170070; called by muse, mutect2, varscan2
- ERBB3 | c.235-2A>G p.X79_splice | Splice Site (SNP) | VAF 101/316 reads (32%) | catalogued as COSV99916998; called by muse, mutect2, varscan2
- ERBB4 | c.226T>A p.F76I | Missense Mutation (SNP) | VAF 30/438 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53506960; called by muse, mutect2
- ERICH1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 116/482 reads (24%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.009); catalogued as rs139686055; called by muse, mutect2, varscan2
- ERVW-1 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 101/544 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); catalogued as COSV101423861; called by muse, mutect2, varscan2
- ESRRB | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 236/756 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.553); catalogued as COSV55059780; called by muse, mutect2, varscan2
- ETNPPL | c.1466C>T p.T489I | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as rs1459500503, COSV99625453; called by muse, mutect2
- EVC | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 165/488 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0.046); catalogued as rs1376630547; called by muse, mutect2, varscan2
- EWSR1 | c.1852C>A p.P618T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.137); catalogued as COSV58423855; called by muse, mutect2
- EXT1 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 151/518 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs1252579899, COSV65485622; called by muse, mutect2, varscan2
- EYS | c.5720T>C p.I1907T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1470118447; called by muse, mutect2, varscan2
- F2 | c.926G>T p.R309M | Missense Mutation (SNP) | VAF 192/619 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV61317071; called by muse, varscan2
- F8 | c.6710C>T p.A2237V | Missense Mutation (SNP) | VAF 76/230 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1314854; called by muse, mutect2, varscan2
- FAF1 | c.1948G>T p.E650* | Nonsense Mutation (SNP) | VAF 35/88 reads (40%) | catalogued as COSV65635818; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 74/220 reads (34%) | catalogued as rs751966944; called by mutect2, varscan2
- FAM193A | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 97/235 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs150844151, COSV61191393, COSV61195732; called by muse, mutect2, varscan2
- FAM200B | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs888205121; called by muse, mutect2
- FAM214A | c.1513del p.R505Gfs*27 | Frame Shift Del (DEL) | VAF 41/125 reads (33%) | catalogued as COSV55927133; called by mutect2, pindel, varscan2
- FAM216A | c.436+1G>A p.X146_splice | Splice Site (SNP) | VAF 31/93 reads (33%) | catalogued as COSV100889732; called by muse, mutect2, varscan2
- FAM227A | c.940A>G p.R314G | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as rs1039394443; called by muse, mutect2, varscan2
- FAM50B | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 112/356 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs753583616; called by muse, mutect2, varscan2
- FAM83H | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs782349627; called by muse, mutect2, varscan2
- FASTKD2 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 12/174 reads (7%) | catalogued as COSV99378744; called by muse, mutect2
- FAT4 | c.10010A>G p.Y3337C | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs745988075; called by muse, mutect2, varscan2
- FAT4 | c.10943G>A p.S3648N | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV100628153; called by muse, mutect2, varscan2
- FBN3 | c.6498C>T p.D2166= | Splice Region (SNP) | VAF 106/328 reads (32%) | catalogued as COSV54472152; called by muse, mutect2, varscan2
- FBXO15 | c.851G>A p.G284D | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs928221584, COSV54046395; called by muse, mutect2, varscan2
- FBXO7 | c.1352G>A p.R451K | Missense Mutation (SNP) | VAF 88/326 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99832537; called by muse, mutect2, varscan2
- FBXW7 | c.808C>T p.Q270* (on ENST00000281708 / NM_001349798.2; = p.Q190* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV104381727, COSV55911231; called by muse, mutect2, varscan2
- FCRL3 | c.656G>T p.R219M | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs575879706, COSV63840625, COSV63844510; called by muse, mutect2, varscan2
- FGD1 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1383316675; called by muse, mutect2, varscan2
- FGF10 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV52934254; called by muse, mutect2, varscan2
- FGF23 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 171/430 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as rs557303699; called by muse, mutect2, varscan2
- FGFRL1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs533496126; called by muse, mutect2, varscan2
- FHL3 | c.157-1G>T p.X53_splice | Splice Site (SNP) | VAF 62/181 reads (34%) | catalogued as COSV65952558; called by muse, mutect2, varscan2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as COSV58769165; called by mutect2, varscan2
- FLG | c.3731C>T p.A1244V | Missense Mutation (SNP) | VAF 24/566 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1251865424; called by muse, mutect2
- FLG | c.2428A>G p.T810A | Missense Mutation (SNP) | VAF 173/522 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV64239651; called by muse, mutect2, varscan2
- FLG | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 164/489 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs757922040, COSV100911849; called by muse, mutect2, varscan2
- FLNA | c.735G>T p.E245D | Missense Mutation (SNP) | VAF 125/416 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV61047746; called by muse, mutect2, varscan2
- FLNA | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 140/421 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1287150584; called by muse, mutect2, varscan2
- FNDC1 | c.5359G>A p.V1787M | Missense Mutation (SNP) | VAF 74/275 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51934963; called by muse, mutect2, varscan2
- FOLH1 | c.1527G>A p.M509I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57048538, COSV99922971; called by muse, mutect2, varscan2
- FOXD2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.168); catalogued as COSV58303997; called by muse, mutect2
- FOXM1 | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 160/399 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.845); catalogued as rs1196473651; called by muse, mutect2, varscan2
- FOXS1 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV54066971; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.845del p.F282Sfs*15 | Frame Shift Del (DEL) | VAF 29/138 reads (21%) | catalogued as rs751624085; called by mutect2, pindel, varscan2
- FRY | c.6149C>T p.A2050V | Missense Mutation (SNP) | VAF 43/598 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1177663842; called by muse, mutect2
- FSCN3 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 71/261 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs763899096; called by muse, mutect2, varscan2
- FSIP2 | c.7957A>G p.K2653E | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1559029105; called by muse, mutect2, varscan2
- FTMT | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 95/294 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58420373, COSV58421761; called by muse, mutect2, varscan2
- G6PC3 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 52/683 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs779143230; called by muse, mutect2
- G6PD | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV63703083; called by muse, mutect2, varscan2
- GABBR1 | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs1286308621; called by muse, mutect2, varscan2
- GABRA1 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.931); catalogued as COSV99195693; called by muse, varscan2
- GAD2 | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV99392835; called by muse, mutect2, varscan2
- GALNT11 | c.1039A>G p.M347V | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349406412; called by muse, mutect2, varscan2
- GAPT | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV59246842, COSV59247312; called by muse, mutect2, varscan2
- GAS1 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 226/638 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1352555335, COSV53926778; called by muse, mutect2, varscan2
- GAS7 | c.1346G>A p.R449Q (on ENST00000432992 / NM_201433.2; = p.R309Q on NM_003644.3) | Missense Mutation (SNP) | VAF 82/285 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs562657250, COSV60437821; called by muse, mutect2, varscan2
- GCNT7 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs797016143; called by muse, mutect2, varscan2
- GDAP2 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751290033; called by muse, mutect2, varscan2
- GDF2 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs200079721; called by muse, mutect2, varscan2
- GDF2 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs782596402; called by muse, mutect2
- GEMIN5 | c.3698G>A p.R1233Q | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs768529762; called by muse, mutect2, varscan2
- GFI1B | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 144/402 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.123); catalogued as rs938560000; called by muse, mutect2, varscan2
- GGT6 | c.1249G>T p.G417W (on ENST00000574154 / NM_001122890.3; = p.G385W on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/370 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99625832; called by muse, mutect2, varscan2
- GHITM | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as rs1421440435, COSV100930134; called by muse, mutect2, varscan2
- GJA3 | c.377C>A p.P126Q | Missense Mutation (SNP) | VAF 145/407 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53835203; called by muse, mutect2, varscan2
- GJB3 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 188/488 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777376931; called by mutect2, varscan2
- GK2 | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.021); catalogued as COSV62627460; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 51/147 reads (35%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLI1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373249560, COSV57364723; called by muse, mutect2
- GLIS3 | c.851G>A p.S284N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1475645380; called by muse, mutect2, varscan2
- GLRA1 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 207/630 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs1008065494; called by muse, mutect2, varscan2
- GLT6D1 | c.416C>A p.T139N | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs201060314; called by muse, mutect2, varscan2
- GMPR | c.344G>A p.S115N | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99440608; called by muse, mutect2, varscan2
- GNAT1 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.859); catalogued as rs764263965; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 24/145 reads (17%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GOLGA3 | c.3824A>C p.Q1275P | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV99202324; called by muse, mutect2
- GOLIM4 | c.1891del p.R631Gfs*87 | Frame Shift Del (DEL) | VAF 32/103 reads (31%) | catalogued as rs1210775698; called by mutect2, pindel, varscan2
- GORASP1 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220542590; called by muse, mutect2
- GP5 | c.1327G>A p.V443M | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as rs532116069; called by muse, mutect2, varscan2
- GPATCH2L | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 114/334 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140982927; called by muse, mutect2, varscan2
- GPI | c.909+8C>T | Splice Region (SNP) | VAF 136/396 reads (34%) | catalogued as rs1392511302; called by muse, varscan2
- GPR146 | c.521G>C p.R174P | Missense Mutation (SNP) | VAF 149/560 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV52465431, COSV52466314; called by muse, mutect2, varscan2
- GPR157 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778088921; called by muse, mutect2, varscan2
- GPR4 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV100546993; called by muse, mutect2, varscan2
- GPR6 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 197/513 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV51573715; called by muse, mutect2, varscan2
- GRAMD1A | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs760215740; called by muse, mutect2, varscan2
- GRIK3 | c.2401C>T p.R801W | Missense Mutation (SNP) | VAF 129/320 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1232964890, COSV66140837; called by muse, mutect2, varscan2
- GRIN2B | c.4036G>A p.E1346K | Missense Mutation (SNP) | VAF 123/383 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.12); catalogued as rs766060662, COSV101663026; called by muse, mutect2, varscan2
- GRIN2D | c.2106G>T p.Q702H | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV99616077; called by muse, mutect2
- GRIN3B | c.2458G>A p.V820I | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as COSV99313061; called by muse, mutect2
- GRIP1 | c.2485G>T p.G829* (on ENST00000359742 / NM_001379345.1; = p.G777* on NM_021150.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 28/394 reads (7%) | catalogued as COSV99671367; called by muse, mutect2
- GRM1 | c.3403A>G p.S1135G | Missense Mutation (SNP) | VAF 64/995 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs778637784; called by muse, mutect2
- GRM5 | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.996); catalogued as COSV100552577; called by muse, mutect2, varscan2
- GSC2 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 103/244 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as rs782694211; called by muse, mutect2, varscan2
- GSTP1 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1212970570; called by muse, mutect2, varscan2
- GTF2I | c.1259A>G p.E420G (on ENST00000573035 / NM_032999.4; = p.E379G on NM_001518.5) | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1417975794; called by muse, mutect2, varscan2
- GTF3C1 | c.6044G>A p.G2015D | Missense Mutation (SNP) | VAF 83/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62241019; called by muse, mutect2, varscan2
- GUCY2D | c.3044-8C>T | Splice Region (SNP) | VAF 162/623 reads (26%) | catalogued as COSV99644090; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | catalogued as COSV54945907; called by mutect2, varscan2
- GYG1 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 104/266 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs769173594; called by muse, mutect2, varscan2
- HACL1 | c.81+1G>A p.X27_splice | Splice Site (SNP) | VAF 12/286 reads (4%) | catalogued as rs1041771993; called by muse, mutect2
- HARS1 | c.1220C>T p.T407M | Missense Mutation (SNP) | VAF 57/266 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs760726168; called by muse, mutect2, varscan2
- HAS1 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 117/360 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs771434906, COSV55788069; called by muse, mutect2, varscan2
- HCFC1 | c.3197A>G p.Q1066R | Missense Mutation (SNP) | VAF 91/264 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs1557114440; called by muse, mutect2, varscan2
- HCFC2 | c.1284+2T>C p.X428_splice | Splice Site (SNP) | VAF 7/45 reads (16%) | catalogued as COSV57558808; called by muse, mutect2, varscan2
- HCN2 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 114/327 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.359); catalogued as rs769405251; called by muse, varscan2
- HCN2 | c.2572G>A p.A858T | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1205274491; called by muse, mutect2, varscan2
- HCN4 | c.2098C>T p.R700* | Nonsense Mutation (SNP) | VAF 171/476 reads (36%) | catalogued as COSV56081039; called by muse, mutect2, varscan2
- HDAC11 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV55473476; called by muse, mutect2, varscan2
- HDAC9 | c.2213G>A p.S738N | Missense Mutation (SNP) | VAF 73/391 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV67772493; called by muse, mutect2, varscan2
- HECTD4 | c.9718del p.A3240Rfs*26 | Frame Shift Del (DEL) | VAF 32/136 reads (24%) | catalogued as rs754540615; called by mutect2, varscan2
- HERC2 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs759964244; called by muse, mutect2, varscan2
- HIRA | c.2489C>T p.T830M | Missense Mutation (SNP) | VAF 98/327 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200432766, COSV54276470; called by muse, mutect2, varscan2
- HIVEP3 | c.6706C>T p.R2236W | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs201095392, COSV56014651; called by muse, mutect2, varscan2
- HIVEP3 | c.6331C>T p.R2111W | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs371175921; called by muse, varscan2
- HIVEP3 | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.494); catalogued as rs951825410; called by muse, mutect2, varscan2
- HK1 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 146/731 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as rs1564547774, COSV53865059; called by muse, mutect2, varscan2
- HK3 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 134/449 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs756469070, COSV99458913; called by muse, mutect2, varscan2
- HLA-C | c.473C>T p.T158I | Missense Mutation (SNP) | VAF 191/802 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as rs41543518; called by muse, varscan2
- HLA-F | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as COSV52574424; called by muse, mutect2, varscan2
- HM13 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as COSV59438307; called by muse, mutect2, varscan2
- HMCN1 | c.6951G>T p.Q2317H | Missense Mutation (SNP) | VAF 17/402 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.748); catalogued as COSV99624327; called by muse, mutect2
- HMCN1 | c.9613G>A p.G3205R | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); catalogued as rs775194711, COSV99630079; called by muse, varscan2
- HMCN2 | c.10915G>A p.A3639T | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as rs1414093604, COSV52984044; called by muse, mutect2, varscan2
- HMCN2 | c.11746G>A p.A3916T | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as rs1352095078, COSV52983452; called by muse, varscan2
- HMOX2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs1225999422; called by muse, mutect2, varscan2
- HNRNPA1 | c.519C>G p.H173Q | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99267473; called by muse, mutect2, varscan2
- HNRNPH3 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs1341725930, COSV99769182; called by muse, mutect2, varscan2
- HOOK2 | c.1680G>T p.K560N | Missense Mutation (SNP) | VAF 117/377 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV53403240; called by muse, mutect2, varscan2
- HOXB2 | c.272del p.P91Rfs*8 | Frame Shift Del (DEL) | VAF 90/264 reads (34%) | catalogued as rs761024113; called by mutect2, varscan2
- HOXC12 | c.593G>A p.G198D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.025); catalogued as rs1404691621; called by muse, mutect2
- HOXC13 | c.131del p.G44Vfs*95 | Frame Shift Del (DEL) | VAF 33/105 reads (31%) | catalogued as rs775869095; called by mutect2, pindel, varscan2
- HPS6 | c.1627G>A p.V543M | Missense Mutation (SNP) | VAF 80/1175 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as rs768226610; called by muse, mutect2
- HS3ST4 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100503241; called by muse, mutect2, varscan2
- HSP90AA1 | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as rs190621788; called by muse, varscan2
- HSPA12A | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536208223, COSV65023054; called by muse, varscan2
- HSPB11 | c.262T>C p.W88R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV52040222; called by muse, mutect2, varscan2
- HSPG2 | c.6860C>T p.A2287V | Missense Mutation (SNP) | VAF 117/374 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.426); catalogued as rs1159326179, COSV101020532; called by muse, mutect2, varscan2
- HSPG2 | c.1730T>C p.L577P | Missense Mutation (SNP) | VAF 130/391 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV65969185; called by muse, mutect2, varscan2
- HTR1B | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.893); catalogued as COSV100885485; called by muse, mutect2
- HTR3D | c.511+6C>T | Splice Region (SNP) | VAF 77/186 reads (41%) | catalogued as rs151016920; called by muse, mutect2, varscan2
- HYAL3 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs144495825; called by muse, mutect2, varscan2
- IARS1 | c.3772A>G p.T1258A | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.061); catalogued as rs749829010; called by muse, mutect2, varscan2
- IDH3B | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 147/1017 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs527817401, COSV100250080; called by muse, mutect2, varscan2
- IFNLR1 | c.794G>T p.R265L | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV59527436; called by muse, mutect2, varscan2
- IFT122 | c.3154-1G>A p.X1052_splice (on ENST00000348417 / NM_052989.3; = p.X993_splice on NM_018262.4) | Splice Site (SNP) | VAF 133/495 reads (27%) | catalogued as rs1217106326; called by muse, mutect2, varscan2
- IGDCC4 | c.1411G>T p.G471C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs201037111; called by muse, mutect2, varscan2
- IGF1R | c.284G>A p.S95N | Missense Mutation (SNP) | VAF 74/810 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV51399608; called by muse, mutect2
- IGFL1 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 49/663 reads (7%) | catalogued as COSV101473080; called by muse, mutect2
- IGHG3 | c.1224C>G p.S408R | Missense Mutation (SNP) | VAF 151/518 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs781085368; called by muse, mutect2, varscan2
- IGHV2-5 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 219/583 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs781835510; called by muse, mutect2, varscan2
- IGHV3-38 | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 75/270 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as rs755802828; called by muse, mutect2, varscan2
- IGLON5 | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1280211677; called by muse, mutect2, varscan2
- IGLV3-22 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 121/370 reads (33%) | catalogued as rs569134161; called by muse, mutect2, varscan2
- IGSF8 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 135/368 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs1291950981, COSV58757380; called by muse, mutect2, varscan2
- IKZF1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 122/513 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV58781912, COSV58785360; called by muse, mutect2, varscan2
- IL17RE | c.416C>A p.S139Y | Missense Mutation (SNP) | VAF 97/268 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV55969177; called by muse, mutect2, varscan2
- ILK | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 312/933 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as rs377094824; called by muse, mutect2, varscan2
- ILVBL | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1443724744, COSV99654658; called by muse, mutect2, varscan2
- IMPDH2 | c.956A>G p.D319G | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752303460; called by muse, mutect2, varscan2
- INHBB | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 125/415 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371205927; called by muse, mutect2, varscan2
- INO80D | c.2501A>G p.H834R | Missense Mutation (SNP) | VAF 99/314 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.698); catalogued as rs542653405; called by muse, mutect2, varscan2
- INSC | c.1395G>A p.M465I | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV65413045; called by muse, mutect2, varscan2
- INTS1 | c.4903G>A p.D1635N | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.239); catalogued as rs1466639536; called by muse, mutect2, varscan2
- IPO9 | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 73/234 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV64233855; called by muse, mutect2, varscan2
- IPP | c.1607A>G p.Y536C | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051855877; called by muse, mutect2, varscan2
- IQSEC3 | c.2257C>T p.R753W (on ENST00000538872 / NM_001170738.2; = p.R450W on NM_015232.1) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555094576, COSV58284293; called by muse, mutect2, varscan2
- IREB2 | c.1121T>C p.M374T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs142912507; called by mutect2, varscan2
- IREB2 | c.2576C>T p.A859V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs149013825; called by muse, varscan2
- ISL1 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 78/312 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV57936069; called by muse, mutect2
- ITGA1 | c.1196A>G p.Y399C | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1424282293; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1501C>T p.P501S (on ENST00000439118 / NM_001008949.3; = p.P509S on NM_178495.6) | Missense Mutation (SNP) | VAF 98/282 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV63153584; called by muse, mutect2, varscan2
- JAK1 | c.2251G>T p.E751* | Nonsense Mutation (SNP) | VAF 69/175 reads (39%) | catalogued as COSV61093179; called by muse, mutect2, varscan2
- JAK1 | c.1289dup p.L431Vfs*22 | Frame Shift Ins (INS) | VAF 34/99 reads (34%) | catalogued as rs755650243; called by mutect2, varscan2
- JAK3 | c.2180G>A p.S727N | Missense Mutation (SNP) | VAF 68/266 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs1268243456, COSV71685546; called by muse, mutect2, varscan2
- JAKMIP3 | c.2323G>A p.V775M | Missense Mutation (SNP) | VAF 132/444 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs753977860; called by muse, mutect2, varscan2
- JAM3 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 147/810 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as rs774867477, COSV54449879; called by muse, varscan2
- KANK1 | c.3583G>A p.A1195T | Missense Mutation (SNP) | VAF 95/262 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101206892; called by muse, mutect2, varscan2
- KAT7 | c.1520del p.P507Qfs*11 | Frame Shift Del (DEL) | VAF 60/157 reads (38%) | catalogued as COSV52014412; called by mutect2, pindel, varscan2
- KATNIP | c.2442G>T p.W814C | Missense Mutation (SNP) | VAF 153/394 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV99851028; called by muse, mutect2, varscan2
- KBTBD13 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.047); catalogued as COSV101416714; called by muse, mutect2, varscan2
- KBTBD2 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs768853563, COSV58362957; called by muse, mutect2, varscan2
- KCNC4 | c.1105G>A p.V369M | Missense Mutation (SNP) | VAF 82/228 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs932458338; called by muse, mutect2, varscan2
- KCND1 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 124/406 reads (31%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.055); catalogued as rs782058830; called by mutect2, varscan2
- KCNH2 | c.3048del p.A1017Pfs*40 | Frame Shift Del (DEL) | VAF 66/271 reads (24%) | catalogued as CD064567; called by mutect2, pindel, varscan2
- KCNH4 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs369685674; called by muse, mutect2, varscan2
- KCNH7 | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 133/370 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV59794210; called by muse, varscan2
- KCNJ12 | c.971del p.G324Vfs*40 | Frame Shift Del (DEL) | VAF 24/258 reads (9%) | catalogued as COSV59169177; called by mutect2, varscan2
- KCNQ5 | c.2078C>T p.T693M | Missense Mutation (SNP) | VAF 167/440 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs777062053, COSV59649876; called by muse, mutect2, varscan2
- KCTD15 | c.380A>G p.D127G | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.905); catalogued as COSV52288908; called by muse, mutect2, varscan2
- KDM2B | c.3751G>A p.V1251I | Missense Mutation (SNP) | VAF 61/572 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs200642027; called by muse, mutect2, varscan2
- KDM4D | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1163149356, COSV58636974; called by muse, mutect2, varscan2
- KIAA1522 | c.1667G>A p.R556H (on ENST00000373480 / NM_001198972.2; = p.R615H on NM_020888.3) | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202138317; called by muse, mutect2, varscan2
- KIAA2013 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs746276599; called by muse, varscan2
- KIF1B | c.3079C>T p.R1027* (on ENST00000377086 / NM_001365952.1; = p.R981* on NM_015074.3) | Nonsense Mutation (SNP) | VAF 45/152 reads (30%) | catalogued as rs886042662, COSV104380392; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF7 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 91/288 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1367383569, COSV101067415; called by muse, mutect2, varscan2
- KIFC2 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 107/353 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs754768081; called by muse, mutect2, varscan2
- KLC3 | c.1219C>A p.L407I | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs751051691; called by muse, mutect2, varscan2
- KLF14 | c.316del p.E106Kfs*66 | Frame Shift Del (DEL) | VAF 54/211 reads (26%) | catalogued as rs1554471037; called by mutect2, pindel, varscan2
- KLHL29 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99942995; called by muse, mutect2, varscan2
- KLHL33 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1037119585; called by muse, mutect2, varscan2
- KLHL38 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 145/452 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as rs767946435; called by mutect2, varscan2
- KLHL5 | c.628dup p.M210Nfs*8 | Frame Shift Ins (INS) | VAF 20/54 reads (37%) | catalogued as rs757382348; called by mutect2, varscan2
- KMT2D | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 63/368 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.92); catalogued as rs1410821210, COSV56422000; called by muse, mutect2, varscan2
- KNDC1 | c.3302A>G p.D1101G | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); catalogued as rs763516318; called by muse, mutect2, varscan2
- KPNB1 | c.2480C>T p.T827I | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1211315139; called by muse, mutect2, varscan2
- KPRP | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 111/346 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs765434263, COSV64220950; called by muse, varscan2
- KREMEN2 | c.1322C>T p.A441V (on ENST00000303746 / NM_172229.3; = p.P415S on NM_024507.4) | Missense Mutation (SNP) | VAF 107/288 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.14); catalogued as rs747033806, COSV99233788; called by muse, mutect2, varscan2
- KRT74 | c.1540C>A p.Q514K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.027); catalogued as COSV59770683; called by muse, mutect2, varscan2
- KRTAP4-9 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 136/541 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as rs774382260; called by muse, varscan2
- KRTAP5-9 | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 131/450 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.029); catalogued as COSV73200208; called by muse, mutect2, varscan2
- KY | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 18/178 reads (10%) | catalogued as rs762212832; called by muse, mutect2, varscan2
- LAMA2 | c.7600C>T p.P2534S | Missense Mutation (SNP) | VAF 104/313 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.743); catalogued as rs1355440441; called by muse, mutect2, varscan2
- LAMB3 | c.3490C>T p.R1164C | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs540971405, COSV50520677; called by muse, mutect2
- LAMC1 | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 80/338 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773378039; called by muse, mutect2
- LARGE1 | c.59G>A p.C20Y | Missense Mutation (SNP) | VAF 178/538 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs1050093594; called by muse, mutect2, varscan2
- LARP6 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0.038); catalogued as rs1243908179; called by muse, mutect2, varscan2
- LCLAT1 | c.293C>T p.T98I | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV58373772; called by muse, mutect2
- LCOR | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs1323264760, COSV53714783; called by muse, mutect2
- LEPROT | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.047); catalogued as rs1239438185; called by muse, mutect2, varscan2
- LHFPL1 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.604); catalogued as rs138438376; called by muse, mutect2
- LILRB3 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 304/1316 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.726); catalogued as rs771814376; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs370336999, COSV99524097; called by muse, mutect2, varscan2
- LLGL1 | c.1611+2T>C p.X537_splice | Splice Site (SNP) | VAF 31/138 reads (22%) | catalogued as COSV100375842; called by muse, varscan2
- LMAN1L | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as rs1307842297; called by muse, varscan2
- LMTK3 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.199); catalogued as rs1396928085; called by muse, mutect2, varscan2
- LOXL2 | c.2318C>T p.P773L | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs780126714, COSV56120559, COSV56120605; called by muse, mutect2, varscan2
- LPCAT1 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs140641175; called by muse, mutect2, varscan2
- LRFN3 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1172016113; called by muse, mutect2, varscan2
- LRIF1 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 28/96 reads (29%) | catalogued as rs375319628; called by muse, mutect2, varscan2
- LRIG1 | c.1112T>C p.I371T | Missense Mutation (SNP) | VAF 69/367 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs764578109; called by muse, mutect2, varscan2
- LRP1 | c.11335G>A p.D3779N | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs755974434, COSV99676923; called by muse, mutect2, varscan2
- LRP2 | c.9203G>A p.C3068Y | Missense Mutation (SNP) | VAF 24/532 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55540346; called by muse, mutect2
- LRP4 | c.3463G>T p.G1155W | Missense Mutation (SNP) | VAF 213/755 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66134185; called by muse, mutect2, varscan2
- LRRC14B | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 232/723 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs376582746; called by muse, mutect2, varscan2
- LRRC4 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 122/507 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1331151059; called by muse, mutect2, varscan2
- LRRC4C | c.1601T>C p.V534A | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as COSV53422786; called by muse, mutect2, varscan2
- LRRC73 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as rs1296024422; called by muse, mutect2, varscan2
- LRRK1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 130/405 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1046335520; called by muse, mutect2, varscan2
- LRRN2 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 171/516 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174838462; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs766558457; called by muse, mutect2, varscan2
- LYPD6 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1411831587; called by muse, mutect2, varscan2
- MADD | c.1537C>A p.L513M | Missense Mutation (SNP) | VAF 91/662 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1204341349; called by mutect2, varscan2
- MAEA | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 20/369 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.158); catalogued as rs1424783804; called by muse, mutect2
- MAGEB10 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 102/437 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs779588937, COSV100775385; called by muse, mutect2, varscan2
- MAGEB6B | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 160/477 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as rs1201916295; called by muse, mutect2, varscan2
- MAGI3 | c.3854G>T p.R1285L | Missense Mutation (SNP) | VAF 124/335 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.321); catalogued as COSV56834734; called by muse, mutect2, varscan2
- MAP1LC3A | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 102/262 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV54160839; called by muse, mutect2, varscan2
- MAP3K12 | c.2020G>T p.G674C | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as COSV99913075; called by muse, mutect2, varscan2
- MAP7D3 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs765772763, COSV60171342; called by mutect2, varscan2
- MAPK11 | c.707T>C p.M236T | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.227); catalogued as rs1412362803; called by muse, mutect2, varscan2
- MAPK4 | c.1504G>T p.G502C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs866384416; called by muse, varscan2
- MAVS | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.037); catalogued as rs144671697, CM1513624; called by muse, mutect2, varscan2
- MBTPS1 | c.3082C>T p.P1028S | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs1384634119, COSV58569179; called by muse, mutect2, varscan2
- MCM2 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 34/580 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV99412816; called by muse, mutect2
- MCM2 | c.2387G>A p.R796H | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776421182; called by muse, mutect2, varscan2
- MCM7 | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 169/750 reads (23%) | catalogued as rs561439468, COSV57999776; called by muse, mutect2, varscan2
- MDN1 | c.12209C>T p.T4070M | Missense Mutation (SNP) | VAF 104/279 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs1433289462, COSV65534599; called by muse, mutect2, varscan2
- MED12L | c.2180C>T p.T727I | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.098); catalogued as rs1255538927; called by muse, mutect2, varscan2
- MED13 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1440917847; called by muse, mutect2, varscan2
- MED17 | c.1634G>A p.G545D | Missense Mutation (SNP) | VAF 236/751 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99316210; called by muse, mutect2, varscan2
- MEDAG | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs142057013; called by muse, varscan2
- MELTF | c.1092del p.Y365Tfs*54 | Frame Shift Del (DEL) | VAF 61/186 reads (33%) | catalogued as rs748010566; called by mutect2, pindel, varscan2
- METTL17 | c.997-8G>A | Splice Region (SNP) | VAF 44/155 reads (28%) | catalogued as rs560978004; called by muse, mutect2, varscan2
- MFSD10 | c.805C>A p.L269I | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.194); catalogued as rs776602325; called by muse, mutect2
- MGA | c.9007G>A p.A3003T (on ENST00000219905 / NM_001164273.1; = p.A2794T on NM_001080541.2) | Missense Mutation (SNP) | VAF 49/307 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54961488, COSV99581467; called by muse, mutect2, varscan2
- MGAT3 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 164/427 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57865169; called by muse, mutect2, varscan2
- MIA | c.262-2A>G p.X88_splice | Splice Site (SNP) | VAF 83/186 reads (45%) | catalogued as COSV54571023; called by muse, mutect2, varscan2
- MICAL2 | c.2306C>T p.T769I | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs756589884; called by muse, mutect2, varscan2
- MIDEAS | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs552503088; called by muse, mutect2, varscan2
- MIDEAS | c.106del p.Q36Sfs*6 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as COSV54098507; called by mutect2, pindel, varscan2
- MIGA2 | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 170/454 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99477336; called by muse, mutect2, varscan2
- MKI67 | c.2274G>A p.M758I | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs750132485; called by muse, mutect2, varscan2
- MMP26 | c.611T>C p.L204P | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775578810; called by muse, mutect2, varscan2
- MNT | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1370876590; called by muse, mutect2
- MOGAT3 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 159/656 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs1171487885; called by muse, varscan2
- MORC4 | c.1972C>T p.L658F | Missense Mutation (SNP) | VAF 103/301 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as rs1390374443; called by muse, mutect2, varscan2
- MS4A14 | c.139-1G>T p.X47_splice | Splice Site (SNP) | VAF 7/90 reads (8%) | catalogued as COSV55730063; called by muse, mutect2
- MST1R | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs573668188; called by muse, mutect2, varscan2
- MTHFD1L | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1323982532; called by muse, mutect2, varscan2
- MUC16 | c.2733C>A p.F911L | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV67446871; called by muse, mutect2, varscan2
- MUC21 | c.1516C>A p.L506M | Missense Mutation (SNP) | VAF 136/406 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV66220898; called by muse, mutect2, varscan2
- MUC4 | c.12919C>A p.P4307T (on ENST00000463781 / NM_018406.7; = p.P71T on NM_004532.6) | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs546623970, COSV57800622; called by muse, varscan2
- MUC4 | c.1973T>C p.M658T | Missense Mutation (SNP) | VAF 117/294 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.044); catalogued as rs377666821, COSV62164639; called by muse, mutect2, varscan2
- MUSK | c.2282del p.N761Tfs*107 | Frame Shift Del (DEL) | VAF 261/872 reads (30%) | catalogued as COSV51893320; called by mutect2, pindel, varscan2
- MXD3 | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1238414572; called by muse, mutect2
- MXRA8 | c.968G>A p.G323D | Missense Mutation (SNP) | VAF 107/302 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV58510258; called by muse, mutect2, varscan2
- MYBPC3 | c.3704T>C p.V1235A | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as CM1412261, COSV57032855; called by muse, mutect2, varscan2
- MYH11 | c.5291A>G p.Q1764R | Missense Mutation (SNP) | VAF 73/632 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.167); catalogued as rs981285361; called by muse, mutect2, varscan2
- MYH15 | c.5447C>T p.A1816V | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV99843676; called by muse, mutect2, varscan2
- MYH4 | c.3870G>T p.E1290D | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as COSV55117069; called by muse, mutect2, varscan2
- MYH7 | c.2200C>T p.Q734* | Nonsense Mutation (SNP) | VAF 274/793 reads (35%) | catalogued as CM034555; called by muse, mutect2, varscan2
- MYH7 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 28/568 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as rs1327007939, COSV62517775; ClinVar: uncertain significance; called by muse, mutect2
- MYL7 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 77/367 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99789977; called by muse, mutect2, varscan2
- MYO15B | c.4991G>A p.G1664D | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1279533566; called by muse, mutect2, varscan2
- MYO18B | c.5876C>T p.T1959I | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.368); catalogued as rs1324563022; called by muse, mutect2
- MYO7B | c.3539C>T p.A1180V | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs769952648; called by muse, mutect2
- MYT1L | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1345999424; called by muse, varscan2
- N4BP3 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV51062662; called by muse, mutect2, varscan2
- NAA10 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 219/691 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs781916695; called by muse, mutect2, varscan2
- NARF | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 73/233 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as rs757271058; called by muse, mutect2, varscan2
- NAXE | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 57/419 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs775637983; called by muse, mutect2, varscan2
- NCAN | c.3431G>T p.W1144L | Missense Mutation (SNP) | VAF 99/350 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53054305; called by muse, mutect2, varscan2
- NCAPD3 | c.3924G>A p.M1308I | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1415701341, COSV73187841; called by muse, varscan2
- NCAPD3 | c.478A>G p.K160E | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs766087793; called by muse, mutect2, varscan2
- NCAPG2 | c.2930T>C p.L977P | Missense Mutation (SNP) | VAF 108/426 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.736); catalogued as rs770230137; called by muse, mutect2, varscan2
- NCKAP1L | c.2909G>A p.C970Y | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199509600; called by muse, mutect2, varscan2
- NCR3LG1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 110/393 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.829); catalogued as rs1215656854; called by muse, mutect2, varscan2
- NCSTN | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 74/301 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV54185286; called by muse, mutect2, varscan2
- NDST1 | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 56/854 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766358150; called by muse, mutect2
- NDST4 | c.1813dup p.T605Nfs*22 | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | catalogued as rs1215333204; called by mutect2, pindel, varscan2
- NDUFS4 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 266/738 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs897257699; called by muse, mutect2, varscan2
- NEB | c.12253C>A p.L4085M | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50840414; called by muse, mutect2, varscan2
- NEFM | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 244/730 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55330531; called by muse, mutect2, varscan2
- NELL2 | c.1049A>G p.Y350C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.294); catalogued as rs769587361; called by muse, mutect2, varscan2
- NEO1 | c.1371G>T p.L457F | Missense Mutation (SNP) | VAF 165/460 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV56079237; called by muse, mutect2, varscan2
- NF1 | c.6922-1G>T p.X2308_splice (on ENST00000358273 / NM_001042492.3; = p.X2287_splice on NM_000267.3) | Splice Site (SNP) | VAF 115/330 reads (35%) | catalogued as CS1311546, COSV62201682; called by muse, mutect2, varscan2
- NF2 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 192/670 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs548217466; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFE2 | c.661del p.E221Rfs*13 | Frame Shift Del (DEL) | VAF 68/209 reads (33%) | catalogued as COSV100380730; called by mutect2, pindel, varscan2
- NFRKB | c.2246C>A p.S749Y (on ENST00000446488 / NM_001143835.2; = p.S774Y on NM_006165.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); catalogued as COSV58759662; called by muse, mutect2
- NFYC | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1482810198; called by muse, mutect2, varscan2
- NHLH1 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs768306094, COSV57483288; called by muse, mutect2, varscan2
- NHLRC4 | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471216488; called by muse, mutect2
- NHSL1 | c.4436C>T p.A1479V | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as rs1410811112; called by muse, mutect2, varscan2
- NIPA2 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.357); catalogued as rs781404376; called by muse, varscan2
- NKX6-3 | c.553G>A p.V185M (on ENST00000518699 / NM_001364841.2; = p.V55M on NM_152568.3) | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201681289; called by muse, mutect2
- NLE1 | c.887G>A p.S296N | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as rs1248942542; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | catalogued as COSV69407880; called by mutect2, pindel
- NOBOX | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 127/518 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1270890160, COSV56194147; called by muse, mutect2, varscan2
- NOL8 | c.2386C>T p.H796Y | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374302480; called by muse, mutect2, varscan2
- NOP56 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs368797562; called by muse, mutect2, varscan2
- NOS3 | c.1933C>T p.L645F | Missense Mutation (SNP) | VAF 74/353 reads (21%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.831); catalogued as COSV52496738; called by muse, mutect2, varscan2
- NOTCH1 | c.2597G>A p.C866Y | Missense Mutation (SNP) | VAF 131/438 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763469662; called by muse, mutect2, varscan2
- NOTCH3 | c.6485T>C p.L2162P | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.497); catalogued as rs1399181942; called by muse, mutect2, varscan2
- NPAP1 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.347); catalogued as COSV61504347; called by muse, mutect2, varscan2
- NPC1L1 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 226/823 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs1390043104, COSV56925529; called by mutect2, varscan2
- NPFFR1 | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 44/572 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53332519; called by muse, mutect2
- NPR3 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.259); catalogued as rs201072091; called by muse, mutect2, varscan2
- NR4A2 | c.325dup p.Q109Pfs*3 | Frame Shift Ins (INS) | VAF 112/310 reads (36%) | catalogued as rs774629025; called by mutect2, varscan2
- NRAP | c.4168G>A p.A1390T (on ENST00000359988 / NM_001322945.2; = p.A1355T on NM_006175.4) | Missense Mutation (SNP) | VAF 91/344 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.582); catalogued as rs769200470; called by muse, mutect2, varscan2
- NRG1 | c.1322C>T p.T441M (on ENST00000405005 / NM_013964.5; = p.T446M on NM_013956.5) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.345); catalogued as rs367543167, COSV99828055; ClinVar: not provided; called by muse, mutect2, varscan2
- NRG3 | c.2051G>A p.S684N (on ENST00000404547 / NM_001370084.1; = p.S660N on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/426 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.6); catalogued as COSV99058681; called by muse, mutect2, varscan2
- NRXN2 | c.4873G>A p.A1625T | Missense Mutation (SNP) | VAF 91/244 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.524); catalogued as rs996072033; called by muse, mutect2, varscan2
- NSD1 | c.5920G>T p.E1974* | Nonsense Mutation (SNP) | VAF 18/150 reads (12%) | catalogued as COSV100729757; called by muse, mutect2, varscan2
- NSD2 | c.4043C>T p.P1348L | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs370127436; called by muse, mutect2
- NUDC | c.826-8G>A | Splice Region (SNP) | VAF 231/777 reads (30%) | catalogued as rs1292852070; called by muse, mutect2, varscan2
- NUTM2F | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 72/401 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99480323; called by muse, mutect2, varscan2
- OCA2 | c.531G>A p.W177* | Nonsense Mutation (SNP) | VAF 60/718 reads (8%) | catalogued as COSV62341018; called by muse, mutect2
- ODAPH | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 205/620 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs143319706; called by muse, mutect2, varscan2
- OIT3 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs535158135, COSV61825907; called by muse, mutect2, varscan2
- OLFML1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs1445386235; called by muse, mutect2
- OLFML3 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as rs762111882, COSV100233066, COSV57436848; called by muse, mutect2, varscan2
- OR11H1 | c.202G>T p.G68* | Nonsense Mutation (SNP) | VAF 46/400 reads (12%) | catalogued as COSV99421719; called by mutect2, varscan2
- OR1E2 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV99943528; called by muse, mutect2
- OR1J1 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 72/320 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.013); catalogued as COSV99403153; called by muse, mutect2, varscan2
- OR2A7 | c.532del p.C178Vfs*37 | Frame Shift Del (DEL) | VAF 129/853 reads (15%) | catalogued as rs749245232; called by mutect2, pindel, varscan2
- OR2AG1 | c.152T>C p.M51T | Missense Mutation (SNP) | VAF 37/276 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs1377476721; called by muse, mutect2, varscan2
- OR4A5 | c.146C>A p.A49D | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.288); catalogued as rs747204814, COSV60523509; called by muse, mutect2, varscan2
- OR4C15 | c.202G>A p.G68R (on ENST00000314644; = p.G14R on NM_001001920.2) | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100116178; called by muse, mutect2, varscan2
- OR51B6 | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV66513246; called by muse, mutect2
- OR51E1 | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 85/254 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229459352; called by muse, mutect2, varscan2
- OR52N2 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs776697248; called by muse, mutect2, varscan2
- OR52R1 | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.17); catalogued as rs374884861; called by muse, mutect2
- OR5P3 | c.152G>T p.R51I | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60429201; called by muse, mutect2, varscan2
- OR6B1 | c.566G>A p.C189Y | Missense Mutation (SNP) | VAF 88/372 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1268041350; called by muse, mutect2, varscan2
- OR6B1 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.221); catalogued as rs887708289; called by muse, mutect2, varscan2
- OR8H2 | c.601A>G p.I201V | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.12); catalogued as rs61734225; called by muse, mutect2, varscan2
- OR8U1 | c.734T>C p.M245T | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs1189009968; called by muse, varscan2
- OS9 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 123/426 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs776061695; called by muse, mutect2, varscan2
- OSMR | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs778624076; called by muse, mutect2, varscan2
- OTOF | c.4259A>G p.D1420G (on ENST00000272371 / NM_194248.3; = p.D653G on NM_004802.4) | Missense Mutation (SNP) | VAF 200/606 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1416813237; called by muse, varscan2
- OVOL2 | c.455G>A p.C152Y | Missense Mutation (SNP) | VAF 114/287 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1463561755; called by muse, mutect2, varscan2
- OXER1 | c.231del p.S78Pfs*64 | Frame Shift Del (DEL) | VAF 124/341 reads (36%) | catalogued as rs753912794; called by mutect2, pindel, varscan2
- P4HA3 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs763074825, COSV59041701; called by muse, mutect2, varscan2
- PA2G4 | c.1115del p.K372Rfs*16 | Frame Shift Del (DEL) | VAF 26/103 reads (25%) | catalogued as rs746871475; called by mutect2, varscan2
- PANK2 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 103/377 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV57253642; called by muse, mutect2, varscan2
- PAPSS1 | c.1486A>T p.M496L | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.54); catalogued as COSV54489561; called by mutect2, varscan2
- PARD6B | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as rs1360182824; called by muse, mutect2, varscan2
- PARP10 | c.2932G>A p.A978T | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.275); catalogued as COSV57297354; called by muse, mutect2
- PARS2 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 92/255 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs760576498, COSV64883591; called by muse, mutect2, varscan2
- PAXIP1 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 37/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767327535; called by muse, mutect2, varscan2
- PC | c.3322G>A p.V1108M | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.59); catalogued as rs1280365622, COSV58993222; called by muse, mutect2
- PC | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.461); catalogued as rs748516996; called by muse, mutect2, varscan2
- PCCA | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 77/255 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as rs748401260; called by muse, mutect2, varscan2
- PCCA | c.2150C>T p.T717I | Missense Mutation (SNP) | VAF 109/511 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs548026367; called by muse, mutect2, varscan2
- PCCB | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 159/477 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.974); catalogued as rs1197317905; called by muse, mutect2, varscan2
- PCDH11X | c.1747C>A p.L583I | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53475067; called by muse, mutect2, varscan2
- PCDH15 | c.3298A>G p.R1100G | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.103); catalogued as rs1300035455; called by muse, mutect2, varscan2
- PCDH18 | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.397); catalogued as rs867015556; called by muse, mutect2, varscan2
- PCDHA1 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 134/332 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.806); catalogued as rs782460804, COSV65377037; called by muse, mutect2, varscan2
- PCDHA9 | c.146C>A p.A49E | Missense Mutation (SNP) | VAF 44/764 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65329695; called by muse, mutect2
- PCDHB1 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 97/298 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782409192; called by muse, mutect2, varscan2
- PCDHB6 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 319/930 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.958); catalogued as COSV99171324; called by muse, mutect2, varscan2
- PCDHB8 | c.2092G>A p.V698M | Missense Mutation (SNP) | VAF 256/836 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs782662625, COSV99175661; called by muse, mutect2, varscan2
- PCDHGB4 | c.242G>T p.S81I | Missense Mutation (SNP) | VAF 65/282 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs531546122; called by muse, mutect2, varscan2
- PCLO | c.13799A>G p.Q4600R | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV61651720; called by muse, mutect2, varscan2
- PCMTD2 | c.411G>A p.K137= | Splice Region (SNP) | VAF 22/70 reads (31%) | catalogued as rs1204320580; called by muse, varscan2
- PCNX4 | c.902C>T p.T301I (on ENST00000406854 / NM_001330177.2; = p.T67I on NM_022495.5) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.122); catalogued as rs766369292; called by muse, mutect2, varscan2
- PCOLCE | c.894del p.K299Sfs*41 | Frame Shift Del (DEL) | VAF 54/243 reads (22%) | catalogued as rs755349242; called by mutect2, pindel, varscan2
- PDE2A | c.2338C>T p.L780F | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); catalogued as COSV57812060; called by muse, mutect2, varscan2
- PDE5A | c.1655A>G p.Q552R | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV53345766; called by muse, mutect2, varscan2
- PDGFA | c.161-4G>A | Splice Region (SNP) | VAF 54/582 reads (9%) | catalogued as COSV63279756; called by muse, mutect2
- PDHA1 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 217/588 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV63328237; called by muse, mutect2, varscan2
- PEAK1 | c.4880G>A p.R1627H | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.413); catalogued as rs774901887, COSV56939690; called by muse, mutect2, varscan2
- PER1 | c.2555C>T p.A852V | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs778854573, COSV57920290; called by muse, mutect2, varscan2
- PER1 | c.1085C>T p.T362M | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753225654; called by muse, mutect2, varscan2
- PER2 | c.3764C>T p.T1255M | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs375456782; called by muse, mutect2, varscan2
- PFKFB1 | c.1013C>T p.T338I | Missense Mutation (SNP) | VAF 8/118 reads (7%) | PolyPhen probably damaging (0.958); catalogued as COSV66629114; called by muse, mutect2
- PHEX | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1051297293, COSV101039456, COSV65079733; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 72/240 reads (30%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF8 | c.1334G>T p.R445M (on ENST00000357988 / NM_001184896.1; = p.R409M on NM_015107.3) | Missense Mutation (SNP) | VAF 105/355 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs782018713; called by muse, mutect2, varscan2
- PHKA1 | c.2444G>A p.G815D | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs781886843; called by muse, mutect2, varscan2
- PHKB | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as rs1424305795, COSV54514811; called by muse, mutect2, varscan2
- PIGA | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 57/305 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.216); catalogued as rs754050083; called by muse, mutect2, varscan2
- PIGG | c.4C>G p.R2G | Missense Mutation (SNP) | VAF 28/480 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV99574309; called by muse, mutect2
- PIGV | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 77/367 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs201084787; called by muse, mutect2, varscan2
- PKD1L1 | c.1565C>T p.T522I | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs1562983395; called by muse, mutect2
- PKDREJ | c.4082A>G p.D1361G | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.469); catalogued as COSV53548924; called by muse, mutect2, varscan2
- PKHD1 | c.6925G>A p.E2309K | Missense Mutation (SNP) | VAF 80/325 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs754303004, COSV61868202; called by muse, mutect2, varscan2
- PLA2G2D | c.89A>G p.K30R | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as rs1489882009; called by muse, mutect2
- PLAGL1 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs529372879, COSV61333125; called by muse, mutect2, varscan2
- PLCH1 | c.2528G>A p.G843E (on ENST00000340059 / NM_001130960.2; = p.G855E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100396190; called by muse, mutect2, varscan2
- PLCXD2 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 22/584 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1203736618; called by muse, mutect2
- PLEKHA1 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as rs1400158709; called by muse, mutect2
- PLEKHA4 | c.1292T>G p.V431G | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs916961233; called by muse, mutect2, varscan2
- PLEKHA8 | c.746A>G p.E249G | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV51651685; called by muse, mutect2, varscan2
- PLEKHG2 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs1347085240; called by muse, mutect2, varscan2
- PLEKHG6 | c.872G>A p.C291Y | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs750755175; called by muse, mutect2, varscan2
- PLIN1 | c.1459G>A p.V487M | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs959529757; called by muse, mutect2, varscan2
- PLIN1 | c.292C>A p.L98M | Missense Mutation (SNP) | VAF 166/473 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475649636; called by muse, mutect2, varscan2
- PLIN3 | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV55734533, COSV55736118; called by muse, mutect2, varscan2
- PLSCR5 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV71649060; called by muse, mutect2, varscan2
- PLSCR5 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 23/119 reads (19%) | catalogued as rs769015012, COSV101494517; called by muse, mutect2, varscan2
- PLXNB3 | c.4963del p.V1655Cfs*7 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | catalogued as rs782076287; called by mutect2, varscan2
- POFUT1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 32/317 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.027); catalogued as rs1306054782; called by muse, mutect2, varscan2
- POGLUT2 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as rs1250852369; called by muse, mutect2, varscan2
- POLDIP2 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.951); catalogued as rs782229878; called by muse, mutect2, varscan2
- POLI | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99471213; called by muse, mutect2, varscan2
- POLM | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 114/519 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs201520546; called by muse, mutect2, varscan2
- POLR2F | c.358del p.V120Wfs*159 | Frame Shift Del (DEL) | VAF 41/195 reads (21%) | catalogued as rs1293095997, COSV62807618; called by mutect2, pindel, varscan2
- POTEI | c.2182del p.R728Gfs*16 | Frame Shift Del (DEL) | VAF 58/506 reads (11%) | catalogued as rs775721804; called by mutect2, pindel
- POU3F2 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 203/603 reads (34%) | catalogued as COSV100099141; called by muse, varscan2
- PPAN-P2RY11 | c.895A>G p.S299G | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs757962826; called by muse, mutect2
- PPFIA4 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as rs1365558916; called by muse, mutect2
- PPFIA4 | c.3034C>T p.R1012W (on ENST00000447715; = p.R1013W on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754229615; called by muse, mutect2, varscan2
- PPIB | c.313G>T p.G105* | Nonsense Mutation (SNP) | VAF 219/712 reads (31%) | catalogued as CM110806, COSV100254343; called by muse, mutect2, varscan2
- PPOX | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 167/476 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1393144931, COSV99237112; called by muse, mutect2, varscan2
- PPP2R3A | c.2246T>C p.M749T | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs1330352854, COSV53868619; called by muse, mutect2, varscan2
- PPP2R3A | c.2984A>G p.Y995C | Missense Mutation (SNP) | VAF 17/261 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1406063802; called by muse, mutect2
- PRDM2 | c.3615T>A p.N1205K | Missense Mutation (SNP) | VAF 68/247 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52444791; called by muse, mutect2, varscan2
- PREX2 | c.3595G>T p.E1199* | Nonsense Mutation (SNP) | VAF 24/189 reads (13%) | catalogued as COSV55791885; called by muse, mutect2, varscan2
- PRKDC | c.8749C>T p.P2917S | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs764745644; called by muse, mutect2, varscan2
- PROC | c.989T>C p.L330P | Missense Mutation (SNP) | VAF 218/609 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM036048; called by muse, mutect2, varscan2
- PROSER1 | c.2694G>T p.Q898H | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1349626703; called by muse, mutect2, varscan2
- PROSER2 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.107); catalogued as COSV53205238; called by muse, mutect2
4,091 further variants in this file (2,313 protein-altering or splice-affecting, 1,151 silent, 627 other) are not listed here.
